CCDI case PBCBUJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/d334acff-823e-4fb9-981f-7578e5aaeeb6

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Solid pseudopapillary tumor: ICD-O-3 morphology code: 8452/1; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 15.0 years (5,488 days).

Biospecimens (3 samples)
- Sample 0DNWJG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNWJO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNWKT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
